Somatic mutation profile of tumor specimen BA2457D (aliquot aq-BA2457D) from BEATAML1.0 case 2375, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.9 years (16,392 days).
Specimen BA2457D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b01388-7d37-4b13-880c-107f62fb3ca0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2196D (Solid Tissue Normal), aliquot aq-BA2196D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffc9d8e3-1de5-48b5-b9e8-9f0cc16d08c1

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, In Frame Ins 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- CATSPER2 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28660230, COSV100390504; called by muse, mutect2, varscan2
- GP2 | c.1468G>A p.D490N (on ENST00000381362 / NM_001007240.3; = p.D487N on NM_001502.4) | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV56894302, COSV56895064; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.145G>C p.D49H (on ENST00000354667 / NM_031243.3; = p.D37H on NM_002137.4) | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61161915; called by muse, mutect2, varscan2
- NWD1 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1369036825, COSV60340671; called by muse, mutect2, varscan2
- SLC13A2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781907961, COSV58999433; called by muse, mutect2, varscan2
- DNAJC6 | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- MCUR1 | c.1065T>A p.Y355* | Nonsense Mutation (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- PBX1 | c.393_404dup p.A132_A135dup | In Frame Ins (INS) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- PTGER4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2
- SH3KBP1 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TIAF1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- TRIM3 | c.1782C>G p.N594K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- VANGL1 | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF284 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FOXE3 | c.219C>T p.P73= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1449219074; called by muse, mutect2, varscan2
- MAMDC4 | c.2766C>T p.G922= (on ENST00000445819; = p.G843= on NM_206920.3) | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs376109252; called by muse, varscan2
- MYNN | c.396T>A p.I132= | Silent (SNP) | VAF 54/230 reads (23%) | called by muse, varscan2
